Surgical pathology report (de-identified scan), TCGA case TCGA-CR-5249, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Vanderbilt University, specimen TCGA-CR-5249-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

DIAGNOSIS: 1) TONSIL, RIGHT, TONSILLECTOMY: BASALOID SQUAMOUS CELL CARCINOMA, 2.2CM IN GREATEST EXTENT (SEE COMMENT).

COMMENT: These findings correspond to AJCC stage II (pT2, pNn/a).

[REDACTED]

CLINICAL DATA

Clinical Features/Dx: unspecified

[REDACTED] [REDACTED]

Operation: unspecified

Operative Findings: unspecified

Operative Diagnosis: unspecified

Tissue Submitted: 1) right tonsil

GROSS DESCRIPTION:

1) SOURCE: Tonsil, Right. Received fresh is a single fragment of red-pink tissue, measuring 3.5 x2.7 x 1.5 cm. The mucosal surface is lobulated, jagged, and irregular. The cauterized surface is inked entirely in blue and is sectioned to reveal a mass of white, irregular tissue, measuring 2.2 x 2.0 x 1.5 cm. The surrounding tissue is pink-tan and normally lobulated. A small portion of tumor is submitted for research. Representative sections are submitted. Summary of sections: 1A-B, 1/1.

[REDACTED]

Slides and report reviewed by Attending Pathologist.

[REDACTED]

[REDACTED]

[REDACTED]

ADDENDUM REPORT

[page 2 of 2]
The following report contains additional information that supplements the previously issued report.

ADDENDUM FINDINGS:

DIAGNOSIS:1) TONSIL, RIGHT, TONSILLECTOMY: BASALOID SQUAMOUS CELL CARCINOMA, 2.2CM IN GREATEST EXTENT; NEGATIVE FOR LYMPHOVASCULAR INVASION; EDGES OF THE SPECIMEN NEGATIVE FOR MALIGNANCY (SEE COMMENT).

COMMENT: These findings correspond to AJCC stage II (pT2, pNn/a).

Electronically signed by: [REDACTED] . [REDACTED]
Slides and report reviewed by Attending Pathologist.

Source: NCI Genomic Data Commons file f8c07092-ed3a-4528-aa94-c0c42b04a421 (TCGA-CR-5249.F17B05FC-B033-42F9-984F-6BF20FC5C1CE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).